Somatic mutation profile of tumor specimen TCGA-DK-A6AV-01A (aliquot TCGA-DK-A6AV-01A-12D-A30E-08) from TCGA case TCGA-DK-A6AV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 82.4 years (30,089 days).
Specimen TCGA-DK-A6AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73eb8cb9-5c51-4ffe-9be3-f181c94d0e56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A6AV-10A (Blood Derived Normal), aliquot TCGA-DK-A6AV-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/128cb565-1283-4a99-8302-dbc8dc40f788

The open-access MAF lists 142 somatic variants for this specimen: 97 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 41, Nonsense Mutation 9, Frame Shift Del 2, Frame Shift Ins 2, Splice Region 2, RNA 2, Intron 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15536G>A p.R5179H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs267607237, CM105472, COSV56428259, COSV56447076, COSV56496109; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.4052C>A p.A1351D (on ENST00000372530 / NM_001198934.2; = p.A1323D on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs1370908453, COSV55095076; called by muse, mutect2, varscan2
- ABCC8 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs956046843, COSV56859093; called by muse, mutect2, varscan2
- AGTR1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | catalogued as COSV100836918, COSV100837216; called by muse, mutect2, varscan2
- AHR | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV54121264, COSV99619199; called by muse, mutect2
- ALMS1 | c.8042C>G p.S2681* | Nonsense Mutation (SNP) | VAF 130/310 reads (42%) | catalogued as CM074697, COSV100040995; called by muse, mutect2, varscan2
- ANKK1 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV58274817; called by muse, mutect2, varscan2
- ANKRD52 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV57288085, COSV99921351; called by muse, mutect2, varscan2
- APOB | c.4890C>G p.I1630M | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); catalogued as COSV51928621, COSV51957237; called by muse, mutect2, varscan2
- ARHGAP28 | c.814G>T p.D272Y (on ENST00000383472 / NM_001366230.1; = p.D113Y on NM_001010000.3) | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV51648260; called by muse, mutect2, varscan2
- ARID2 | c.3568G>T p.G1190* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as COSV57598442; called by muse, mutect2, varscan2
- ARL16 | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 86/297 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV61270744; called by muse, mutect2, varscan2
- ASAP2 | c.1681G>T p.G561* | Nonsense Mutation (SNP) | VAF 30/167 reads (18%) | catalogued as COSV99855680; called by muse, mutect2, varscan2
- ASMT | c.663C>A p.H221Q (on ENST00000381229; = p.H249Q on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.406); catalogued as COSV67110465; called by muse, mutect2, varscan2
- ASPM | c.7462C>G p.Q2488E | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54141225; called by muse, mutect2, varscan2
- ATP5PB | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52386404; called by muse, mutect2, varscan2
- ATR | c.5263C>G p.Q1755E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as COSV63384509, COSV63393892; called by muse, mutect2, varscan2
- BAP1 | c.43T>G p.F15V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56239201, COSV56242082; called by muse, mutect2, varscan2
- BPIFB6 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62756988; called by muse, mutect2, varscan2
- C9orf24 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); catalogued as rs755114901, COSV52625750; called by muse, mutect2, varscan2
- CAPN15 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV99562129; called by muse, mutect2
- CARD10 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV52657104; called by muse, mutect2, varscan2
- CASP7 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61883613; called by muse, mutect2, varscan2
- CCDC120 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.916); catalogued as COSV64515079, COSV64515908; called by muse, mutect2, varscan2
- CCS | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs777662396, COSV100039720; called by muse, mutect2, varscan2
- CFAP94 | c.1990G>T p.E664* (on ENST00000320267 / NM_001352064.2; = p.E670* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100208873; called by muse, mutect2, varscan2
- COG5 | c.1615C>T p.L539F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); catalogued as rs749455454, COSV51767102; called by muse, mutect2, varscan2
- COL11A1 | c.2656-1G>A p.X886_splice | Splice Site (SNP) | VAF 25/105 reads (24%) | catalogued as COSV62201787; called by muse, mutect2, varscan2
- CRACD | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs774810416, COSV51734029; called by muse, mutect2, varscan2
- CSMD3 | c.6902A>G p.D2301G (on ENST00000297405 / NM_001363185.1; = p.D2197G on NM_052900.3) | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV52348586; called by muse, mutect2, varscan2
- CTNNB1 | c.2095G>C p.D699H | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as COSV62725553; called by muse, mutect2, varscan2
- CYP2A6 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV99991707; called by muse, mutect2, varscan2
- CYP2A7 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as rs768997550, COSV52501369; called by muse, mutect2, varscan2
- DNAH2 | c.7618G>T p.V2540F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV66728776; called by muse, mutect2, varscan2
- DST | c.6226C>G p.P2076A | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV55046433; called by muse, mutect2, varscan2
- DYNC2I1 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1463786353, COSV68107765; called by muse, mutect2, varscan2
- FAT1 | c.9406G>C p.E3136Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV71676320, COSV71676325; called by muse, mutect2, varscan2
- FBXO21 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100401647, COSV57975377; called by muse, mutect2, varscan2
- FLCN | c.499C>G p.Q167E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as CM1310106, COSV53264093; called by mutect2, varscan2
- GBX1 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52548196; called by muse, mutect2, varscan2
- GDPD2 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100978532; called by muse, mutect2, varscan2
- GPATCH1 | c.2262C>G p.F754L | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50132256; called by muse, mutect2, varscan2
- GSPT2 | c.1763C>A p.T588K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61215433; called by muse, mutect2, varscan2
- HSPB8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs757293016, COSV56136872, COSV56137127, COSV56137340; called by muse, mutect2, varscan2
- IKZF2 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1487594941, COSV59578897; called by muse, mutect2, varscan2
- KCNV2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV66056568; called by muse, mutect2, varscan2
- KIFC3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs782261569, COSV65553579; called by muse, mutect2, varscan2
- KRT73 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV59837718, COSV59842040; called by muse, mutect2, varscan2
- LAMB4 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV52733280; called by muse, mutect2, varscan2
- LGI2 | c.759C>A p.N253K | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV66122481, COSV66124315; called by muse, mutect2, varscan2
- LPA | c.1089G>C p.Q363H | Missense Mutation (SNP) | VAF 77/573 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as rs746045757, COSV100305976; called by muse, mutect2, varscan2
- LRRN4 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.381); catalogued as rs199665734, COSV66645194; called by muse, mutect2, varscan2
- LSM14A | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV101471650; called by muse, mutect2
- MAGEC1 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53583002; called by muse, mutect2, varscan2
- MTMR1 | c.347T>A p.I116N | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64900202; called by muse, mutect2, varscan2
- MTREX | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV57929586, COSV57930989; called by muse, mutect2, varscan2
- MYCBP2 | c.11581C>A p.L3861M (on ENST00000357337; = p.L3899M on NM_015057.5) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62042914; called by muse, mutect2, varscan2
- MYH1 | c.4365G>A p.K1455= | Splice Region (SNP) | VAF 31/70 reads (44%) | catalogued as COSV56858816; called by muse, mutect2, varscan2
- NUP42 | c.221_222del p.D74Afs*10 | Frame Shift Del (DEL) | VAF 39/158 reads (25%) | catalogued as COSV51731586; called by mutect2, pindel, varscan2
- PCDH15 | c.4252G>A p.A1418T | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV57303574; called by muse, varscan2
- PCDHGA1 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.627); catalogued as rs768240411, COSV65296000; called by muse, mutect2, varscan2
- PHACTR2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as rs751328298, COSV59860575; called by muse, mutect2, varscan2
- PLA2G2E | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV64291099; called by muse, mutect2, varscan2
- PLXNA4 | c.3075G>C p.R1025S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV58166552; called by muse, mutect2, varscan2
- PRAG1 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460095688, COSV58168096; called by muse, mutect2, varscan2
- PRSS12 | c.969C>T p.L323= | Splice Region (SNP) | VAF 6/51 reads (12%) | catalogued as COSV56610358; called by muse, mutect2, varscan2
- PRX | c.1330C>A p.L444I | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as COSV52534217; called by muse, varscan2
- PSMC6 | c.571G>T p.G191C (on ENST00000612399; = p.G177C on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71629472; called by muse, mutect2, varscan2
- RAB8B | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1467129427, COSV58491468; called by muse, mutect2, varscan2
- RIPOR1 | c.2641G>A p.E881K (on ENST00000379312 / NM_001193522.2; = p.E877K on NM_024519.4) | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV50287061; called by muse, mutect2, varscan2
- RP1 | c.1329G>C p.K443N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs368559909, CD152739; called by muse, mutect2, varscan2
- RPS6KA6 | c.1936G>A p.G646S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.745); catalogued as COSV53128432; called by muse, mutect2, varscan2
- RYR1 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62113684; called by muse, mutect2
- SETD5 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56711191, COSV56718374; called by muse, mutect2, varscan2
- SHANK2 | c.5358G>T p.W1786C | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53623682, COSV99573419; called by muse, mutect2, varscan2
- SMC6 | c.1906del p.A636Lfs*25 | Frame Shift Del (DEL) | VAF 37/102 reads (36%) | catalogued as COSV61179166; called by mutect2, pindel, varscan2
- SUN2 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752150588, COSV53307617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYCP1 | c.1351A>G p.K451E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV65701677; called by muse, mutect2, varscan2
- TARS1 | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV54312974; called by muse, mutect2, varscan2
- TMPRSS9 | c.3163C>T p.R1055W (on ENST00000648592; = p.R1021W on NM_182973.2) | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747763355, COSV53115567; called by muse, mutect2, varscan2
- TRIM71 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 44/152 reads (29%) | catalogued as COSV101070370; called by muse, mutect2, varscan2
- TTBK1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs763736859, COSV52493698; called by muse, mutect2, varscan2
- TULP3 | c.689A>T p.N230I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV68118960; called by muse, mutect2, varscan2
- TYK2 | c.3244T>C p.S1082P | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53392841; called by muse, mutect2, varscan2
- UBR2 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV65753186; called by muse, mutect2, varscan2
- VSIG10 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1478528593, COSV63654668; called by muse, mutect2, varscan2
- ZDHHC5 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.112); catalogued as COSV54709663; called by muse, mutect2, varscan2
- ZNF254 | c.1474T>C p.C492R | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439133062, COSV61645279; called by muse, mutect2, varscan2
- ZNF683 | c.450C>G p.F150L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV62876182; called by muse, mutect2, varscan2
- ZNF764 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV53222853; called by muse, mutect2, varscan2
- ZNF764 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1444989432, COSV99410927; called by muse, mutect2
- ZXDC | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100306273; called by muse, mutect2, varscan2
- ABI3BP | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2
- CCR8 | c.950_954dup p.C319Kfs*10 | Frame Shift Ins (INS) | VAF 11/117 reads (9%) | called by mutect2, pindel
- DNAJC15 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- FANCB | c.2088_2096del p.R696_G698del | In Frame Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel
- NFX1 | c.2513dup p.R839Efs*12 | Frame Shift Ins (INS) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.5481A>G p.P1827= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as COSV50820350; called by muse, mutect2, varscan2
- ANO6 | c.1203A>C p.A401= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV57669653; called by muse, mutect2, varscan2
- BFSP2 | c.63G>A p.Q21= | Silent (SNP) | VAF 47/145 reads (32%) | catalogued as COSV56592774; called by muse, mutect2, varscan2
- BMPR2 | c.1245G>A p.E415= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs1415707996, COSV65814078; called by muse, mutect2, varscan2
- CBX4 | c.162G>T p.L54= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99490185; called by muse, mutect2
- CD248 | c.1044C>T p.I348= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV60937845; called by muse, mutect2, varscan2
- CDH3 | c.294C>G p.S98= | Silent (SNP) | VAF 43/254 reads (17%) | catalogued as COSV50581651; called by muse, mutect2, varscan2
- CDH3 | c.1104C>T p.I368= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as rs1030235776, COSV50554815, COSV50581898; called by muse, mutect2, varscan2
- CELSR2 | c.1779G>A p.S593= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs775831069, COSV54780832; called by muse, mutect2, varscan2
- COL4A5 | c.4458C>G p.G1486= | Silent (SNP) | VAF 47/187 reads (25%) | catalogued as COSV60374462; called by muse, mutect2, varscan2
- CPB1 | c.141G>A p.T47= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs779840672, COSV51572419; called by muse, mutect2, varscan2
- DIAPH3 | c.3012C>T p.F1004= (on ENST00000400324 / NM_001042517.2; = p.F741= on NM_030932.3) | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV57370372, COSV57383319, COSV99932550; called by muse, mutect2, varscan2
- DMD | c.9444G>A p.L3148= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV58959967; called by mutect2, varscan2
- FCAR | c.255C>T p.F85= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV62028749; called by muse, mutect2, varscan2
- FLNB | c.6477C>T p.P2159= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV55899379; called by muse, mutect2, varscan2
- GHITM | c.18G>A p.L6= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs373805264; called by muse, mutect2, varscan2
- GIPR | c.177C>T p.L59= | Silent (SNP) | VAF 66/157 reads (42%) | catalogued as COSV54423208, COSV54423522; called by muse, mutect2, varscan2
- HMX3 | c.759C>T p.S253= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV63502051; called by muse, mutect2, varscan2
- LAMB4 | c.4770T>C p.I1590= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV52733267; called by muse, mutect2, varscan2
- LRTOMT | c.578G>A p.*193= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99194373; called by muse, mutect2
- MAML1 | c.2268C>G p.L756= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs764755840, COSV52989501; called by muse, mutect2, varscan2
- MED12 | c.963T>C p.S321= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV61359048; called by muse, mutect2, varscan2
- MEGF6 | c.939G>A p.A313= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs1165361728; called by muse, mutect2
- OTOA | c.1635T>C p.S545= (on ENST00000286149; = p.S531= on NM_144672.4) | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV53766352; called by muse, mutect2, varscan2
- PCDHA12 | c.2178G>A p.P726= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs1389969210, COSV56554513; called by muse, mutect2, varscan2
- PCDHA4 | c.1710G>T p.A570= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV63546627, COSV63547076; called by muse, mutect2, varscan2
- RAB5B | c.345G>T p.V115= | Silent (SNP) | VAF 23/198 reads (12%) | catalogued as COSV64365382; called by muse, mutect2, varscan2
- RNLS | c.384C>T p.F128= | Silent (SNP) | VAF 80/174 reads (46%) | catalogued as COSV59301760; called by muse, mutect2, varscan2
- RUVBL2 | c.231C>G p.G77= | Silent (SNP) | VAF 21/213 reads (10%) | catalogued as COSV55487764, COSV99668863; called by muse, mutect2, varscan2
- RYR1 | c.372C>G p.R124= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as COSV62113678; called by muse, mutect2
- SLC13A1 | c.477C>T p.I159= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1363431980, COSV52018016; called by muse, mutect2, varscan2
- TMEM151A | c.136C>T p.L46= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV59175683; called by muse, mutect2
- TRIL | c.1425G>A p.L475= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1223995249, COSV59868216; called by muse, mutect2, varscan2
- TTC17 | c.2430G>A p.L810= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs376589348; called by muse, mutect2, varscan2
- TTC31 | c.1002C>T p.L334= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as rs1258579999, COSV52037642; called by muse, mutect2, varscan2
- UNC93B1 | c.1395G>A p.E465= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- WDR48 | c.357C>T p.Y119= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs752206294, COSV56534855; called by muse, mutect2, varscan2
- WDR70 | c.69C>T p.V23= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV54286238; called by muse, mutect2, varscan2
- ZBTB40 | c.2970G>A p.P990= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs753041868, COSV65146653; called by muse, mutect2, varscan2
- ZNF326 | c.531G>A p.T177= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs768718091, COSV61034841; called by muse, mutect2, varscan2
- ZNF554 | c.1593G>A p.Q531= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV57887331; called by muse, mutect2, varscan2
- C17orf58 | c.103+124G>A | Intron (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100558697; called by muse, mutect2, varscan2
- DCHS2 | n.80T>C | RNA (SNP) | VAF 5/19 reads (26%) | catalogued as COSV59741649; called by muse, mutect2, varscan2
- MIR506 | n.44A>G | RNA (SNP) | VAF 47/88 reads (53%) | called by muse, mutect2, varscan2
- QKI | c.934+26A>G | Intron (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99274116; called by muse, mutect2, varscan2
